Somatic mutation profile of tumor specimen TCGA-CJ-4644-01A (aliquot TCGA-CJ-4644-01A-02D-1386-10) from TCGA case TCGA-CJ-4644, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 49.0 years (17,882 days).
Specimen TCGA-CJ-4644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7dd8122-9645-49a6-94d2-eca492ff5d15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4644-11A (Solid Tissue Normal), aliquot TCGA-CJ-4644-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a78b7246-d740-43c4-9e32-494cec8d8ac9

The open-access MAF lists 59 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 2, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6016G>C p.V2006L | Missense Mutation (SNP) | VAF 87/224 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV63868121, COSV63871144, COSV63874589; called by muse, varscan2
- ADGRL1 | c.2547G>C p.E849D (on ENST00000340736 / NM_001008701.3; = p.E844D on NM_014921.5) | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV61566275; called by muse, mutect2, varscan2
- ADGRV1 | c.7391T>C p.F2464S | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.655); catalogued as COSV67993086; called by muse, mutect2
- ATG2B | c.2601A>C p.E867D | Missense Mutation (SNP) | VAF 102/616 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV63424929; called by muse, mutect2
- ATP11C | c.2618T>C p.I873T | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV100558237; called by muse, mutect2
- ATP2A1 | c.2158A>T p.M720L | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV62870652; called by muse, mutect2, varscan2
- CDCA2 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs746714079, COSV57948002; called by muse, mutect2, varscan2
- COG3 | c.549+2T>C p.X183_splice | Splice Site (SNP) | VAF 48/222 reads (22%) | catalogued as COSV63074669; called by muse, mutect2, varscan2
- COG4 | c.414C>G p.D138E | Missense Mutation (SNP) | VAF 82/329 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1349239369, COSV60424651; called by muse, mutect2, varscan2
- CTNNA3 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV65602250; called by muse, mutect2
- EOMES | c.1240A>C p.N414H | Missense Mutation (SNP) | VAF 150/337 reads (45%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.921); catalogued as COSV55414822; called by muse, mutect2, varscan2
- EPN1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99322099; called by muse, varscan2
- FLG2 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 34/344 reads (10%) | catalogued as rs763012686, COSV66166291; called by muse, mutect2
- FMNL1 | c.3133G>T p.E1045* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV58958623; called by muse, mutect2, varscan2
- FRY | c.3834G>T p.M1278I | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV66577020; called by muse, mutect2, varscan2
- GNAS | c.569G>A p.G190D | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV58343969; called by muse, mutect2, varscan2
- HHIPL2 | c.1582C>A p.L528I | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.768); catalogued as COSV58567093; called by muse, mutect2, varscan2
- HOXD3 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 63/232 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.054); catalogued as COSV50884442; called by muse, mutect2, varscan2
- IPO8 | c.2521C>A p.L841M | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV56244729; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs977606848, COSV59827510; called by muse, mutect2, varscan2
- KIF5C | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 35/505 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776184580, COSV68483300; called by muse, mutect2
- KLHL31 | c.1883C>A p.S628Y | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV63882252; called by muse, mutect2, varscan2
- LIMS1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 32/340 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100185974, COSV57541602; called by muse, mutect2, varscan2
- MPHOSPH10 | c.739G>T p.G247W | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV54906846; called by muse, mutect2
- MRPL3 | c.280T>G p.S94A | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.776); catalogued as COSV53915773; called by muse, mutect2
- MUC16 | c.2574T>G p.H858Q | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.331); catalogued as COSV67485656; called by muse, mutect2, varscan2
- NKAIN3 | c.554G>T p.C185F | Missense Mutation (SNP) | VAF 71/283 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV60679097; called by muse, mutect2, varscan2
- OR4F15 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 92/406 reads (23%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV59970004; called by mutect2, varscan2
- OTOP1 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 6/77 reads (8%) | catalogued as rs200368405; called by muse, mutect2
- PBRM1 | c.237-1G>A p.X79_splice | Splice Site (SNP) | VAF 64/148 reads (43%) | catalogued as COSV56291984, COSV56295403, COSV56297184; called by muse, mutect2, varscan2
- PCDHA6 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as COSV65342295; called by muse, mutect2, varscan2
- PDZRN3 | c.2861G>T p.R954L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370428084; called by muse, mutect2, varscan2
- PUM2 | c.3145A>T p.N1049Y | Missense Mutation (SNP) | VAF 160/942 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV57584345; called by muse, mutect2, varscan2
- PYROXD1 | c.1437G>C p.M479I | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs772910152, COSV53711355; called by muse, mutect2, varscan2
- RBM44 | c.511C>T p.Q171* (on ENST00000611254; = p.Q805* on NM_001080504.2) | Nonsense Mutation (SNP) | VAF 138/381 reads (36%) | catalogued as COSV57632601; called by muse, mutect2, varscan2
- SLC35B3 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 52/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59469586; called by muse, mutect2
- SRRM1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60479965; called by muse, mutect2, varscan2
- SYNE2 | c.194del p.H65Lfs*7 | Frame Shift Del (DEL) | VAF 119/428 reads (28%) | catalogued as COSV99049383; called by mutect2, pindel, varscan2
- TTN | c.68360T>C p.I22787T (on ENST00000591111; = p.I15363T on NM_003319.4) | Missense Mutation (SNP) | VAF 31/381 reads (8%) | PolyPhen benign (0.439); catalogued as rs746112857, COSV60272876; called by muse, mutect2
- TTN | c.59807G>A p.C19936Y (on ENST00000591111; = p.C12512Y on NM_003319.4) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | PolyPhen possibly damaging (0.837); catalogued as COSV60272919; called by muse, mutect2, varscan2
- VHL | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 56/148 reads (38%) | catalogued as COSV56550372, COSV56552968, COSV56563522; called by muse, mutect2, varscan2
- ZP4 | c.1622A>T p.*541Lext*? | Nonstop Mutation (SNP) | VAF 124/393 reads (32%) | catalogued as COSV63913186; called by muse, mutect2, varscan2
- FCGBP | c.11313G>T p.M3771I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM4A | c.2407del p.L803Wfs*16 | Frame Shift Del (DEL) | VAF 44/169 reads (26%) | called by mutect2, pindel, varscan2
- MGA | c.4344del p.G1449Vfs*31 | Frame Shift Del (DEL) | VAF 13/107 reads (12%) | called by mutect2, pindel, varscan2
- PRUNE2 | c.3970del p.S1324Vfs*21 | Frame Shift Del (DEL) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- HOXD3 | c.99C>T p.G33= | Silent (SNP) | VAF 63/233 reads (27%) | catalogued as COSV50884512; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.22C>T p.L8= | Silent (SNP) | VAF 95/736 reads (13%) | catalogued as rs748438833; called by muse, mutect2, varscan2
- INSC | c.885G>C p.R295= | Silent (SNP) | VAF 72/255 reads (28%) | catalogued as COSV65412597; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.846C>T p.L282= | Silent (SNP) | VAF 77/280 reads (28%) | catalogued as COSV56442755; called by muse, mutect2, varscan2
- MMP25 | c.528C>T p.R176= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs371570478; called by muse, mutect2, varscan2
- OBSL1 | c.2598G>T p.L866= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV54709786; called by muse, mutect2, varscan2
- PTCHD3 | c.810C>T p.Y270= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs376677291; called by muse, mutect2, varscan2
- PUM2 | c.3144G>A p.K1048= | Silent (SNP) | VAF 159/938 reads (17%) | catalogued as COSV57584355; called by muse, mutect2, varscan2
- SLC7A5 | c.606C>T p.A202= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1485547239, COSV55366404; called by muse, mutect2, varscan2
- SLC7A8 | c.216G>T p.V72= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV57555524; called by muse, mutect2
- TCP11 | c.1509T>C p.V503= (on ENST00000512012; = p.V441= on NM_018679.5) | Silent (SNP) | VAF 61/291 reads (21%) | catalogued as COSV55135453; called by muse, mutect2, varscan2
- TMEM41A | c.472T>C p.L158= | Silent (SNP) | VAF 68/250 reads (27%) | catalogued as rs952062258, COSV56188374; called by mutect2, varscan2
- KCNC2 | c.*2C>A | 3'UTR (SNP) | VAF 90/368 reads (24%) | catalogued as COSV100129245; called by mutect2, varscan2
